TCGA case TCGA-X6-A8C6 — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Fibromatous Neoplasms; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: University of Iowa. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/719fa3f6-0194-423d-8a96-3709e8180565

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 55 years; Vital status: Dead; Days to death: 1,067 days (2.9 years).

Diagnoses (12)
1. Fibromyxosarcoma (the primary disease): ICD-O-3 morphology code: 8811/3; ICD-10 code: C49.2; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of lower limb and hip; Classification of tumor: primary; Age at diagnosis: 55.0 years (20,090 days); Year of diagnosis: 2011; Metastasis at diagnosis: No Metastasis; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Tumor focality: Unifocal.
   Pathology details: Measurement type: Radiologic; Tumor burden: 10.1.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved; Necrosis present: No; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Pathologic; Tumor burden: 8.5.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 6.4; Tumor length measurement: 10.1; Tumor width measurement: 7.9.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 6.8; Tumor length measurement: 8.5; Tumor width measurement: 8.3.
2. Hodgkin lymphoma, NOS: ICD-O-3 morphology code: 9650/3; Classification of tumor: Prior primary; Age at diagnosis: 20.1 years (7,355 days); Days to diagnosis: -12,735 days (-34.9 years).
3. Metastasis of diagnosis 1 (Fibromyxosarcoma), site: Long bones of lower limb and associated joints. Age at diagnosis: 56.1 years (20,498 days); Days to diagnosis: 408 days (1.1 years); Prior treatment: Yes; Tumor focality: Multifocal.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 4.8; Tumor length measurement: 7.3; Tumor width measurement: 5.9.
   Pathology details: Measurement type: Pathologic; Tumor burden: 10.7.
   Pathology details: Measurement type: Radiologic; Tumor burden: 7.3.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 6.4; Tumor length measurement: 8; Tumor width measurement: 7.5.
   Pathology details: Additional pathology findings: Well Differentiated.
4. Metastasis of diagnosis 1 (Fibromyxosarcoma), site: Bone, NOS. Age at diagnosis: 56.3 years (20,553 days); Days to diagnosis: 463 days (1.3 years); Prior treatment: Yes.
5. Recurrence of diagnosis 1 (Fibromyxosarcoma), site: Connective, subcutaneous and other soft tissues of pelvis. Age at diagnosis: 57.1 years (20,862 days); Days to diagnosis: 772 days (2.1 years); Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 3.9; Tumor width measurement: 2.9.
6. Metastasis of diagnosis 1 (Fibromyxosarcoma), site: Lung, NOS. Age at diagnosis: 57.1 years (20,862 days); Days to diagnosis: 772 days (2.1 years); Prior treatment: Yes; Tumor focality: Unifocal.
7. Metastasis of diagnosis 1 (Fibromyxosarcoma), site: Vertebral column. Age at diagnosis: 57.1 years (20,862 days); Days to diagnosis: 772 days (2.1 years); Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 1.4.
8. Metastasis of diagnosis 1 (Fibromyxosarcoma), site: Rib, sternum, clavicle and associated joints. Age at diagnosis: 57.1 years (20,862 days); Days to diagnosis: 772 days (2.1 years); Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 2.7.
9. Metastasis of diagnosis 1 (Fibromyxosarcoma), site: Lung, NOS. Age at diagnosis: 57.3 years (20,933 days); Days to diagnosis: 843 days (2.3 years); Prior treatment: Yes; Tumor focality: Unifocal.
10. Recurrence of diagnosis 1 (Fibromyxosarcoma), site: Connective, subcutaneous and other soft tissues of pelvis. Age at diagnosis: 57.3 years (20,933 days); Days to diagnosis: 843 days (2.3 years); Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 4.8; Tumor width measurement: 3.6.
11. Metastasis of diagnosis 1 (Fibromyxosarcoma), site: Lung, NOS. Age at diagnosis: 57.7 years (21,065 days); Days to diagnosis: 975 days (2.7 years); Prior treatment: Yes; Tumor focality: Unifocal.
12. Recurrence of diagnosis 1 (Fibromyxosarcoma), site: Connective, subcutaneous and other soft tissues of pelvis. Age at diagnosis: 57.7 years (21,065 days); Days to diagnosis: 975 days (2.7 years); Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 5.4; Tumor width measurement: 3.8.

Follow-up (10 entries)
- Day 0 (initial diagnosis): Discontiguous lesion count: 1.
- Day 408 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Long bones of lower limb and associated joints; Days to progression: 408 days (1.1 years); Discontiguous lesion count: 2.
- Day 463 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 463 days (1.3 years); Discontiguous lesion count: 2.
- Days to follow up: 749 days (2.1 years); Disease response: With Tumor.
- Day 772 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Connective, subcutaneous and other soft tissues of pelvis; Days to recurrence: 772 days (2.1 years).
- Day 772 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Vertebral column; Days to progression: 772 days (2.1 years).
- Day 772 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 772 days (2.1 years).
- Day 772 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Rib, sternum, clavicle and associated joints; Days to progression: 772 days (2.1 years).
- Day 843 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Connective, subcutaneous and other soft tissues of pelvis; Days to recurrence: 843 days (2.3 years).
- Days to follow up: 1,067 days (2.9 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-X6-A8C6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 380 mg.
  Slide TCGA-X6-A8C6-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-X6-A8C6-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-X6-A8C6-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Myxofibrosarcoma; Margin status: Positive; Tumor total necrosis: 0% (no necrosis or no mention of necrosis); Disease multifocal indicator: No; Discontinuous lesions count: 1; Locoregional recurrence indicator: No; Metastatic disease confirmed: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Lower Extremity - Thigh/knee.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease.
- Drug treatment 1: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 785; Days from index date to pharmaceutical treatment ended: 840; Pharmaceutical therapy drug name: Doxirubicin; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 2: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 911; Days from index date to pharmaceutical treatment ended: 966; Pharmaceutical therapy drug name: Gemcitabine; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Radiation treatment 1: Days from index date to radiation therapy started: 714; Days from index date to radiation therapy ended: 718; Radiation therapy type: External; Radiation total dose: 27; Radiation adjuvant units: Gy; Radiation adjuvant fractions total: 3; Radiation therapy site: Distant site; Radiation therapy ongoing indicator: No.
- Radiation treatment 2: Days from index date to radiation therapy started: 120; Days from index date to radiation therapy ended: 165; Radiation therapy type: External; Radiation total dose: 6400; Radiation adjuvant units: cGy; Radiation adjuvant fractions total: 32; Radiation therapy site: Primary Tumor Field; Radiation therapy ongoing indicator: No; Treatment best response: Complete Response.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Lymphoma; Other malignancy histological type: Hodgkin Lymphoma.
- Other malignancy form, Surgery: Other malignancy surgery type: splenectomy.
- Other malignancy form, Radiation treatment: History radiation treatment to site of TCGA tumor: No; Days from index date to radiation therapy started: -12704.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,067 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,067 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 408 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-X6-A8C6-01A-11D-A36I-01): tumor purity 0.35, ploidy 5.37, whole-genome doublings 2.
